Somatic mutation profile of tumor specimen TCGA-BQ-7060-01A (aliquot TCGA-BQ-7060-01A-11D-1961-08) from TCGA case TCGA-BQ-7060, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.3 years (19,479 days).
Specimen TCGA-BQ-7060-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7fd1b4c-0379-40c5-9b7e-686e0165efa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7060-11A (Solid Tissue Normal), aliquot TCGA-BQ-7060-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91ac5e28-f106-4cd8-b95a-a5271a13b6e9

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Frame Shift Del 4, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP11A | c.1932T>G p.F644L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV55705197; called by muse, mutect2, varscan2
- DGKG | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs1358054415, COSV53961710; called by muse, mutect2, varscan2
- DLGAP1 | c.2879C>A p.T960N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59784979, COSV59798803; called by muse, mutect2, varscan2
- ERAL1 | c.226T>C p.F76L | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV54739223; called by muse, mutect2, varscan2
- FUT6 | c.923T>A p.L308Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99744842; called by muse, mutect2, varscan2
- KDM6A | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV65037300; called by muse, mutect2, varscan2
- KLHL8 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1035441776, COSV56746862; called by muse, mutect2
- NAA16 | c.835A>T p.I279F | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV65064213, COSV65065136; called by muse, mutect2, varscan2
- NOTCH2 | c.6457T>A p.S2153T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as CD118396, COSV56682261, COSV99863085; called by muse, mutect2, varscan2
- NSMCE3 | c.685C>G p.R229G | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54263293, COSV54274493; called by muse, mutect2, varscan2
- POLQ | c.7160A>G p.Y2387C | Missense Mutation (SNP) | VAF 173/351 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51746084; called by muse, mutect2, varscan2
- POP1 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV62891898; called by muse, mutect2, varscan2
- SPATA6 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100893358; called by muse, mutect2, varscan2
- ST7 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55380186; called by muse, mutect2, varscan2
- SVEP1 | c.9668T>G p.L3223R | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.399); catalogued as rs756766136, COSV52835649; called by muse, mutect2, varscan2
- TEP1 | c.6925G>A p.E2309K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52988189; called by muse, mutect2, varscan2
- TMC5 | c.2231C>G p.S744C (on ENST00000396229 / NM_001105248.1; = p.S498C on NM_024780.5) | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.115); catalogued as rs1452081483, COSV54900994; called by muse, mutect2, varscan2
- TNKS1BP1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV64099991; called by muse, mutect2, varscan2
- ZNF619 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59029455; called by muse, mutect2, varscan2
- ZNRF3 | c.1181T>C p.V394A (on ENST00000544604 / NM_001206998.2; = p.V294A on NM_032173.3) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as COSV60431386; called by muse, varscan2
- KBTBD4 | c.658del p.R220Efs*12 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- LRBA | c.7279_7280dup p.G2429Lfs*20 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- MAPK8IP3 | c.3407-6_3408delinsG p.X1136_splice | Splice Site (DEL) | VAF 31/87 reads (36%) | called by pindel, varscan2*
- MUL1 | c.628del p.L210Cfs*12 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- MYO6 | c.486del p.K162Nfs*4 | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | called by mutect2, pindel, varscan2
- NSD1 | c.2482del p.S828Lfs*9 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- TAF15 | c.826_832delinsCAAC p.D276_D278delinsQH (on ENST00000605844 / NM_139215.3; = p.D273_D275delinsQH on NM_003487.4) | In Frame Del (DEL) | VAF 23/188 reads (12%) | called by pindel, varscan2*
- BEND2 | c.1536T>A p.I512= | Silent (SNP) | VAF 192/266 reads (72%) | catalogued as COSV66215092; called by muse, mutect2, varscan2
- C16orf70 | c.465T>C p.H155= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as COSV54625617; called by muse, mutect2, varscan2
- C7orf57 | c.132C>A p.L44= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV62361873; called by muse, mutect2, varscan2
- EPHA8 | c.549G>T p.L183= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV51262806, COSV99385502; called by mutect2, varscan2
- ITGAX | c.2211G>A p.T737= | Silent (SNP) | VAF 64/126 reads (51%) | catalogued as rs984893661, COSV51641716, COSV51649751; called by muse, mutect2, varscan2
- KPNA4 | c.378T>C p.D126= | Silent (SNP) | VAF 109/204 reads (53%) | catalogued as COSV62074689; called by muse, mutect2, varscan2
- RPL29 | c.33C>T p.N11= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53685577; called by muse, varscan2
- S1PR2 | c.*1G>A | 3'UTR (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100495350; called by muse, mutect2, varscan2
